Gene-level copy-number profile of tumor specimen TCGA-DU-6399-01A from TCGA case TCGA-DU-6399, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 54.5 years (19,906 days).
Specimen TCGA-DU-6399-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.0480abf8-63b7-41b8-bc98-3e6fb46097db.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DU-6399-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/acbce938-3816-42e6-9737-fb809a62c125

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 5,507; copy number 2: 50,608; copy number 3: 3,705.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DU-6399-01A-12D-1704-01): tumor purity 0.69, ploidy 4, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 3,121. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
